Somatic mutation profile of tumor specimen TCGA-D1-A0ZN-01A (aliquot TCGA-D1-A0ZN-01A-11D-A122-09) from TCGA case TCGA-D1-A0ZN, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 60.3 years (22,026 days).
Specimen TCGA-D1-A0ZN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21ce99c4-fcc0-43cc-87d0-d68ac1022575.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A0ZN-10A (Blood Derived Normal), aliquot TCGA-D1-A0ZN-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a58b20c-0796-4f62-8b17-b439abc2d220

The open-access MAF lists 51 somatic variants for this specimen: 36 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 26, Silent 15, Frame Shift Ins 3, Splice Region 2, Nonsense Mutation 2, Frame Shift Del 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 55/150 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 43/126 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- ACAA2 | c.44C>T p.T15M | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs777732630, COSV53270349; called by muse, mutect2, varscan2
- AKR1C4 | c.93G>C p.R31S | Missense Mutation (SNP) | VAF 70/218 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV54124444; called by muse, mutect2, varscan2
- BRAP | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 97/295 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV58160205; called by muse, mutect2, varscan2
- CACNA1F | c.1655G>A p.G552E | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.08); catalogued as COSV59905812; called by muse, mutect2, varscan2
- COL5A2 | c.4116C>T p.F1372= | Splice Region (SNP) | VAF 122/321 reads (38%) | catalogued as rs755092575, COSV66412086; ClinVar: likely benign; called by muse, mutect2, varscan2
- CXorf58 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 103/298 reads (35%) | catalogued as rs1391932597, COSV64857848; called by muse, mutect2, varscan2
- CYLC1 | c.709A>G p.I237V | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as rs1170464517, COSV61412739; called by muse, mutect2, varscan2
- DGKB | c.1170G>A p.E390= | Splice Region (SNP) | VAF 33/157 reads (21%) | catalogued as rs1157919165, COSV51804089, COSV99341780; called by muse, mutect2, varscan2
- EPG5 | c.4409A>G p.K1470R | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV56353297; called by muse, mutect2, varscan2
- FPR3 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 63/182 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs748290067, COSV59331072; called by muse, mutect2, varscan2
- LILRA4 | c.278C>A p.A93E | Missense Mutation (SNP) | VAF 85/208 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV52493659; called by muse, mutect2, varscan2
- MED13 | c.3689A>G p.N1230S | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs765910362, COSV67265535; called by muse, mutect2, varscan2
- MSL3 | c.103-1G>C p.X35_splice | Splice Site (SNP) | VAF 206/576 reads (36%) | catalogued as COSV56494797; called by muse, mutect2, varscan2
- NLRP14 | c.2907G>T p.L969F | Missense Mutation (SNP) | VAF 85/309 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs757452487, COSV100205468; called by muse, mutect2
- OBSCN | c.16868T>A p.L5623Q | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52802984; called by muse, mutect2, varscan2
- PHF8 | c.2701C>T p.R901W (on ENST00000357988 / NM_001184896.1; = p.R865W on NM_015107.3) | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57684932; called by muse, mutect2, varscan2
- PIK3R1 | c.1728del p.R577Efs*5 (on ENST00000521381 / NM_181523.3; = p.R307Efs*5 on NM_181504.4) | Frame Shift Del (DEL) | VAF 148/450 reads (33%) | catalogued as COSV57131154; called by mutect2, pindel, varscan2
- PRSS16 | c.395G>A p.R132K | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57914758, COSV57916203; called by muse, mutect2, varscan2
- PRTFDC1 | c.352A>G p.M118V | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV60776316; called by muse, mutect2, varscan2
- PTEN | c.778A>T p.K260* | Nonsense Mutation (SNP) | VAF 197/263 reads (75%) | catalogued as rs1554825247, COSV64301699; called by muse, mutect2, varscan2
- RASD2 | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.803); catalogued as rs766600291, COSV53352327; called by muse, mutect2, varscan2
- RTF2 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as COSV50129305, COSV50129973; called by muse, mutect2, varscan2
- SETD2 | c.4177T>G p.L1393V | Missense Mutation (SNP) | VAF 122/313 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs1469670151, COSV57445136; called by muse, mutect2, varscan2
- SLC25A11 | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as COSV52591637; called by muse, mutect2, varscan2
- SNCAIP | c.937A>C p.S313R | Missense Mutation (SNP) | VAF 86/213 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV54416413; called by muse, mutect2, varscan2
- TAF1 | c.1712A>G p.H571R (on ENST00000373790 / NM_138923.4; = p.H592R on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/229 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52120122; called by muse, mutect2, varscan2
- TFF2 | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1348103589, COSV52296846; called by muse, mutect2
- TFPI | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 160/403 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV51903776; called by muse, mutect2, varscan2
- TRIM46 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs939722032, COSV55279721; called by muse, mutect2, varscan2
- WDTC1 | c.868dup p.E290Gfs*7 | Frame Shift Ins (INS) | VAF 28/84 reads (33%) | catalogued as rs747972901; called by mutect2, varscan2
- WRAP73 | c.703A>T p.S235C | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54562522, COSV99573138; called by muse, mutect2, varscan2
- ARID1A | c.3354_3355dup p.A1119Vfs*43 | Frame Shift Ins (INS) | VAF 31/102 reads (30%) | called by mutect2, pindel, varscan2
- GIT2 | c.950_952del p.L317del (on ENST00000355312 / NM_057169.5; = p.L319del on NM_014776.5) | In Frame Del (DEL) | VAF 51/170 reads (30%) | called by pindel, varscan2
- RANBP2 | c.8065dup p.Y2689Lfs*9 | Frame Shift Ins (INS) | VAF 78/235 reads (33%) | called by mutect2, pindel, varscan2
- BMP15 | c.1170A>G p.T390= | Silent (SNP) | VAF 41/120 reads (34%) | catalogued as rs1557280397, COSV53141252; called by muse, mutect2, varscan2
- CFH | c.3573G>A p.S1191= | Silent (SNP) | VAF 216/966 reads (22%) | catalogued as rs774650020, COSV66411127; called by muse, mutect2, varscan2
- FAM135B | c.3924C>T p.V1308= | Silent (SNP) | VAF 88/290 reads (30%) | catalogued as rs746954728, COSV52708502; called by muse, mutect2
- GTF2IRD1 | c.1647C>G p.P549= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV56089425; called by muse, mutect2, varscan2
- HOXD9 | c.135G>A p.A45= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs963709815, COSV50896812; called by muse, mutect2
- LMTK2 | c.3195C>T p.S1065= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs777084457, COSV52000174; called by muse, mutect2, varscan2
- MAP3K9 | c.2523C>T p.S841= (on ENST00000554752 / NM_001284230.1; = p.S855= on NM_033141.4) | Silent (SNP) | VAF 68/211 reads (32%) | catalogued as rs1162833672, COSV67122247; called by muse, mutect2, varscan2
- MUC16 | c.41655G>T p.L13885= | Silent (SNP) | VAF 118/299 reads (39%) | catalogued as COSV66694860; called by muse, mutect2, varscan2
- NLRP7 | c.54C>T p.N18= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as rs142035762; called by muse, mutect2, varscan2
- PCDHB1 | c.2298T>C p.S766= | Silent (SNP) | VAF 13/244 reads (5%) | catalogued as COSV100128390; called by muse, mutect2
- PTPN14 | c.2799C>T p.N933= | Silent (SNP) | VAF 159/625 reads (25%) | catalogued as rs770612272, COSV65286133; called by muse, mutect2, varscan2
- SERPING1 | c.723G>A p.R241= | Silent (SNP) | VAF 103/308 reads (33%) | catalogued as COSV53543640; called by muse, mutect2, varscan2
- SLC35F2 | c.1020C>T p.A340= | Silent (SNP) | VAF 46/106 reads (43%) | catalogued as rs370769369; called by muse, mutect2, varscan2
- TBC1D2 | c.1912C>T p.L638= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as COSV59787066; called by muse, mutect2, varscan2
- UACA | c.2043C>T p.H681= | Silent (SNP) | VAF 115/266 reads (43%) | catalogued as rs146812558; called by muse, mutect2, varscan2
